RC case RC-B658 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cadffb3-b06d-46dc-894d-8ae1df2d7c3c

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1967; Vital status: Dead; Days to death: 362 days; Year of death: 2021; Cause of death: Cancer Related; Country of birth: Guyana.

Diagnoses (3)
1. Anaplastic large cell lymphoma, ALK negative (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,550 days); Year of diagnosis: 2020; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Retroperitoneal / Bone marrow / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.1 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 5 days; Days to treatment end: 117 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin + Cyclophosphamide + Doxorubicin + Etoposide + Prednisone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: BV-CHEP; Days to treatment start: 5 days; Days to treatment end: 117 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 132 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Initial disease status: Progressive Disease; Days to treatment start: 275 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin; Days to treatment start: 357 days; Days to treatment end: 357 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 54.2 years (19,789 days); Days to diagnosis: 239 days.
3. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 54.4 years (19,884 days); Days to diagnosis: 334 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Days to follow up: 160 days; Disease response: Tumor Free.
- Day 239 (end of treatment course 1): Progression or recurrence: Yes; Days to recurrence: 239 days; Imaging type: PET; Imaging result: Negative.
- Day 334 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 334 days.
- Days to follow up: 362 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Follow-up contact recording only the day: day 313.

Molecular and laboratory tests
- Lactate Dehydrogenase 2393 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 50 kg; Height: 157 cm; BMI: 20.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: Glaucoma.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B658-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B658-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
